Surgical pathology report (de-identified scan), TCGA case TCGA-XN-A8T5, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site University of Sao Paulo, specimen TCGA-XN-A8T5-01A (Primary Tumor).

ICD-O-3
Adenocarcinoma duct NOS
CAGE 8500/3
Site: Pancreas head
path C25.0
Pancreas NOS C25.9
Gw 11/29/14

NATURE OF MATERIAL : DUODENUM

BIOPSY :

MACROSCOPY

Product of partial gastrectomy content a segment of duodenum measuring 15 cm in length and 8.0 cm in diameter and a portion of pancreas measuring length of 5.5 cm x 3.0 cm.

MICROSCOPIC EXAMINATION

Product of a "in block" resection of gastric, duodenum and pancreas with:

- moderately differentiated ductal adenocarcinoma , measuring 2.5 cm of extension.
- presence of perineural infiltration.
- angiolymphatic vascular invasion was not detected .
- six free of lymph nodes without neoplasia (0 / 6) .
- pathological stage : pT2 , pN0 .

NOTES

- It was noted a suspicion foci of neuroendocrine differentiation .

PATHOLOGISTS

0 % neuroendocrine - per TSS.
Update 7/9/15 - per TSS, specimen had
60 % ductal
40 % neuroendocrine.
h

APAA Discrepancy		☒

Source: NCI Genomic Data Commons file 392561a7-e835-408a-af69-e75e645d3580 (TCGA-XN-A8T5.776C9B48-C11F-45B9-9C6B-4466306134DD.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).